Surgical pathology report (de-identified scan), TCGA case TCGA-3Z-A93Z, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Mary Bird Perkins Cancer Center - Our Lady of the Lake, specimen TCGA-3Z-A93Z-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient:		Accession:	
DOB:	Age:	Sex:	M
MRN:		Account:	
Requested by:		Patient:	
		Date Collected:	
		Date Received:	
		Date Reported:	

Clinical Data: Right renal mass

FINAL PATHOLOGIC DIAGNOSIS

Right kidney and fat, radical nephrectomy:
- Renal cell carcinoma, clear cell type (see Synoptic Report).

ICD-O-3

Carcinoma, clear cell 8010/3
Site @ Kidney NOS C64.9
W 3/26/14

SYNOPTIC REPORT

Tumor focality:	Solitary
Tumor site:	Right kidney, middle
Tumor size:	3.7 cm in greatest dimension
Histologic type:	Clear cell renal cell carcinoma
Sarcomatoid features:	Not identified
Histologic grade:	Fuhrman nuclear grade II
Extent of involvement:	Confined to kidney
Lymphovascular invasion:	Not identified
Margins:	Uninvolved by tumor Tumor present 0.3 cm from the nearest inked soft tissue margin
Regional lymph nodes:	None submitted
Additional findings:	Benign cortical cyst Adjacent parenchyma with mild interstitial inflammation.
Ancillary studies:	None performed
Pathologic Tumor Stage:	pT1a pNX

Pathologist, Electronic Signature

Intradepartmental consultation: .

SPECIMEN(S) SUBMITTED: GROSS DESCRIPTION

Right kidney and fat: In formalin labeled "right kidney and perinephric fat" is a 424-gram right nephrectomy specimen to include a 10 x 7 x 2.8 cm kidney with attached perinephric soft tissue and 4.5 cm of ureter. The capsular surface is gray-brown and slightly bulging. The specimen is bivalved to reveal a 3.7 x 3.5 cm spongy tan-yellow mass within the mid region, which approaches the renal capsule and comes to within 0.3 cm of the soft tissue margin (inked blue). The mass is focally hemorrhagic and displays smooth-walled cystic spaces containing tan-red fluid. There are additional smooth-walled cystic

[page 2 of 2]
SURGICAL PATHOLOGY REPORT - CONTINUED

Patient: [REDACTED]

Result ID: [REDACTED]

Accession: [REDACTED]

spaces throughout the parenchyma ranging up to 2.5 cm and containing clear fluid. The remaining cut surface displays spongy, pink-brown parenchyma with a well-defined corticomedullary junction. The renal pelvis displays focally hemorrhagic tan-pink urothelium. Ureteral and vascular margins appear free of tumor grossly. No adrenal gland is identified. Representative sections are submitted in seven cassettes as follows: A - ureteral and vascular margins, B - C - mass to include the inked soft tissue margin, D - additional section of mass, E - mass to include adjacent cystic space, F - G - renal parenchyma to include pelvis and cystic spaces.

CPT CODE(S):

88307

ICD-9 CODE(S):

[1890]

FACILITY:

END OF REPORT

Source: NCI Genomic Data Commons file ce8912ac-2680-4b32-acab-0666bdb406f1 (TCGA-3Z-A93Z.33A159F3-8E7E-4B4F-9212-CAF878E94022.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).